Somatic mutation profile of tumor specimen 0DIW7Q from CCDI case PBBUZR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary microcarcinoma; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.4 years (5,256 days).
Specimen 0DIW7Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efd886d4-9a1a-42e4-8822-a2fc3f47c333.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW62 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d69bebb1-4da4-4c35-a85d-84950a945cfb

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 284/1285 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 70/1833 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- IPPK | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 38/1602 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GSG1L2 | c.282G>A p.Q94= | Silent (SNP) | VAF 44/1749 reads (3%) | called by muse, mutect2
- RTL3 | c.108G>A p.Q36= | Silent (SNP) | VAF 69/1623 reads (4%) | catalogued as rs373470836, COSV100329608, COSV58185336; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 43/1495 reads (3%) | called by muse, mutect2
- ZNF546 | c.846T>C p.F282= | Silent (SNP) | VAF 26/1006 reads (3%) | called by muse, mutect2
